Surgical pathology report (de-identified scan), TCGA case TCGA-AF-3914, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-3914-01A (Primary Tumor).

[page 1 of 2]
Recurrent path

1CB-0-3

adenocarcinoma, NOS 8140/3
Site: Rectum, NOS C19.9

fw
10/2/12

Final Surgical Pathology Report

Procedure:

Diagnosis

Rectum with J-pouch, attached bladder and prostate, pelvic exenteration:

Recurrent poorly differentiated adenocarcinoma involving rectal mucosa, submucosa, muscularis propria, perirectal adipose tissue and extensively infiltrating prostatic parenchyma.

Tumor is present at the right pelvic sidewall margins

The prostatic urethral margin is positive for tumor in parenchyma and lymphatic spaces

The rectal mucosal and deep margins are negative for tumor

Extensive lymphovascular space invasion and perineural space invasion

Microscopic Description:

Microscopic examination performed and summarized in the template below:

Histologic type: Recurrent adenocarcinoma

Histologic grade: Poorly differentiated

Primary tumor (pT): Although the tumor with somewhat difficult to define grossly its microscopic spread was quite extensive with prominent involvement of the rectum and J-pouch and connective tissue between the rectum and the prostate and extensive infiltration of the prostate and prostatic urethra and seminal vesicles. Overall the recurrent tumor measured greater than 5 cm in greatest dimension

Proximal margin: Proximal rectal margin negative for tumor

Distal margins: Distal rectal margin negative for tumor

Circumferential (radial) margin: Right pelvic sidewall is microscopically positive for tumor with areas of perineural space invasion. Also tumor was present at the prostatic urethral margin

Vascular invasion: Present and prominent with both lymphatic and venous invasion identified

Regional lymph nodes (pN): 1 residual lymph node was identified and it is negative for metastatic tumor (0/1)

Non-lymph node pericolic tumor: Present

Distant metastasis (pM): Not evaluated

Other findings: There is some acute colitis in the rectum that is nonspecific. There are some nonspecific findings of chronic cystitis in the bladder. The ureter margins were negative for tumor. However some tumor was identified attached to the left side of the bladder in deep nerves attached seminal vesicles.

MSI testing was not ordered as this is a recurrent tumor and not a primary tumor.

Specimen

Bladder prostate and rectum

Clinical Information

Recurrent rectal cancer. Recurrence between J-pouch and prostate/seminal vesicles

Gross Description

Received fresh and subsequently fixed in formalin labeled "bladder prostate and rectum" is a specimen which includes a 4.3 x 3.7 white 3.7 cm prostate, an 8.5 cm portion of rectum with J-pouch, attached bladder and prostate. The bladder is approximately 6.5 x 5.5 and is 4.0 cm inflated. There is a catheter in the prostatic urethra and the specimen is heavily stapled. Orientation of the specimen was reviewed by the surgeon at time of tissue procurement. No frozen sections were requested. Proximal end of the rectum is inked blue and the distal end

[page 2 of 2]
of the rectum is inked black. The J-pouch of the specimen is approximately 3 x 2.5 cm and is heavily stapled, located within 2.5 cm of the distal margin of the rectum. The mucosa of this area is smooth and glistening showing an average circumference of 7.5 cm in its opened state. In the J-pouch there is a 1.2 x 0.7 cm ulcer. This comes within 2.5 cm of the distal rectal margin and 6.5 cm of the proximal rectal margin. This comes within 1.2 cm of the anastomotic line surface of this area shows tumor present and a scarred focus. This area of the J-pouch is adherent to the posterior right side of the prostate. This area is inked black. The cut surface of this area shows a white tan scarred irregular focus which is approximately 2.5 x 2.5 x 2.5 cm. The remainder of the cut surface of the prostate is pink-tan and diffusely nodular. The remainder of the bladder and prostate are opened in an anterior Y-shaped incision. Mucosa the bladder is pink-tan smooth glistening with no other discrete gross lesions identified. The ureters are patent an average 4.5 x 0.3 cm. The seminal vesicles cannot be grossly identified in a variegated and behind the rectum. Vas deferentia cannot be grossly identified. From minimal fat is gross identified surrounding the tissue. Possible lymph nodes may be present. Representative sections of the specimen are submitted as follows: 1 - representative luminal margins of the rectum, 2 - 6 - entire J-pouch ulceration and to tumor including anastomotic line (inked blue) and possible seminal vesicle and prostatic tissue, (from proximal to distal), 7 - left side bladder with ureteral orifice and possible ureteral margin, 7 - right side bladder with possible ureteral margin (ureteral orifice cannot be grossly identified) 9 - representative posterior bladder, 10 - prostatic urethral margin en face, 11 - full thickness prostate from prostatic urethra to rectum, 12 - 14 representative right sided prostate from apex to base, 13 - 17 - representative left prostate from apex to base, 18 - possible lymph node, 19 - 2 possible lymph nodes, 20 through 22 - additional portions of perirectal fat

Source: NCI Genomic Data Commons file 8922e248-ebd6-4f83-a3fb-1ff35035e517 (TCGA-AF-3914.1D26C175-4FCE-4EDB-B91E-DE7A507DC86A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).